FM case AD15370 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/0f72cc8d-1b72-429a-a6a9-8bc79179365a

Male, 70.2 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
